Surgical pathology report (de-identified scan), TCGA case TCGA-22-5479, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-5479-01A (Primary Tumor).

[REDACTED] Surgical Pathology

[REDACTED] CGA-22-5479

DIAGNOSIS:

Lung, left, resection: Grade 3 (of 4) squamous cell carcinoma forming a central 4.5 x 3.0 x 3.0 cm mass arising from the left lower bronchus, near the bifurcation. No pleural invasion is present. The bronchial lumen is occluded and distal obstructive pneumonia is observed. The bronchial margin is negative. Multiple (4) intrapulmonary peribronchial lymph nodes are negative for tumor.

Lymph nodes, superior mediastinal, aortic, inferior mediastinal, and N1, excision: Multiple superior mediastinal (17 right lower paratracheal, 7 left lower paratracheal), aortic (3 subaortic), inferior mediastinal (14 subcarinal), and N1 (1 hilar) lymph nodes are negative for tumor.

Source: NCI Genomic Data Commons file f4978184-5b0d-4f47-b617-bb1b660e40b5 (TCGA-22-5479.63EC0C23-5FFC-4C19-A40B-A314C1C91D36.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).